TCGA case TCGA-02-0332 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/54b4c27e-aaa6-4a79-b289-0ba251a5460e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 46 years; Vital status: Dead; Days to death: 782 days (2.1 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 46.6 years (17,021 days); Year of diagnosis: 1995; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 37 days; Days to treatment end: 82 days; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 99 days; Days to treatment end: 230 days; Number of cycles: 4; Treatment dose: 110 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Procarbazine; Treatment intent type: Adjuvant; Days to treatment start: 99 days; Days to treatment end: 230 days; Number of cycles: 4; Treatment dose: 60 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vincristine; Treatment intent type: Adjuvant; Days to treatment start: 99 days; Days to treatment end: 230 days; Number of cycles: 4; Treatment dose: 1 mg/m2; Route of administration: Intravenous.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 47.8 years (17,459 days); Days to diagnosis: 438 days (1.2 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 438 (post initial treatment): Progression or recurrence: Yes; Days to progression: 438 days (1.2 years).
- Days to follow up: 782 days (2.1 years); Disease response: With Tumor.
- Karnofsky performance status: 80.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-02-0332-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
  Slide TCGA-02-0332-01A-01-BS1: Section location: Bottom; Percent tumor cells: 30; Percent tumor nuclei: 100; Percent normal cells: 20; Percent necrosis: 30; Percent stromal cells: 20.
  Slide TCGA-02-0332-01A-01-TS1: Section location: Top; Percent tumor cells: 25; Percent tumor nuclei: 100; Percent normal cells: 50; Percent necrosis: 25.
- Sample TCGA-02-0332-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Ccnu.
- Drug treatment 1, Route of administrations: Route of administration: IV.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 782 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 782 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 438 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-02-0332-01): tumor purity 0.88, ploidy 4.05, whole-genome doublings 1 (call status: legacy_call).
